Gene-level copy-number profile of tumor specimen ALCH-ADRQ-TTP1-A from ALCHEMIST case ALCH-ADRQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,358 days).
Specimen ALCH-ADRQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fcf73d63-a4e9-4d8f-8d5b-0f6a9d281cee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADRQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/c0d602fe-2c07-42d8-9699-cd33705ad7b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 1,928; copy number 2: 54,603; copy number 3: 1,720; copy number 4: 9; copy number 5: 5; copy number 6: 3; copy number 7: 23; copy number 10: 30; copy number 15: 17.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,711,525–231,711,647, 1 gene (within-gene range 0–1): U4.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr8:143,857,324–143,878,467, 1 gene: EPPK1.
- chr10:101,226,195–101,229,794, 1 gene (within-gene range 0–2): LBX1.
- chr11:69,147,228–69,171,564, 2 genes: AP003071.2, SMIM38.
- chr15:25,169,337–25,238,067, 38 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr16:4,795,265–4,802,880, 2 genes (within-gene range 0–2): AC020663.2, ROGDI.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr19:7,898,804–7,919,157, 5 genes (within-gene range 0–2): AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2.
- chr19:12,682,693–12,687,279, 1 gene: AC010422.2.
- chr19:12,688,922–12,689,238, 1 gene (within-gene range 0–2): AC018761.4.
- chr19:50,996,007–51,009,634, 3 genes (within-gene range 0–2): KLK8, AC011473.4, KLK9.
- chr22:18,855,621–18,894,407, 3 genes (within-gene range 0–6): BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:65,824,460–65,966,291, 1 gene, copy number 7 (within-gene range 2–7): HMGA2.
- chr12:65,851,340–69,224,242, 68 genes, copy number 7–15 (broad region; genes not listed).
- chr12:83,151,331–83,172,740, 2 genes, copy number 5: RPL6P25, AC090680.1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 6: PWP2.
- chr21:44,172,169–44,194,338, 2 genes, copy number 5: AP001056.2, AP001056.1.
- chr22:18,636,445–18,719,341, 3 genes, copy number 5–7: CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,846,811–18,861,049, 1 gene, copy number 6 (within-gene range 0–6): AC008132.1.

Autosomal genes at a single copy (total copy number 1): 1,928. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
